Somatic mutation profile of tumor specimen 0DCBJ2 from CCDI case PBBMEG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 1.8 years (646 days).
Specimen 0DCBJ2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b5f482e-a749-4854-a185-588ec8989818.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCBIV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43fc28ad-3e7d-4fef-8378-14629bb1656c

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Nonsense Mutation 1, Intron 1, RNA 1, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD7 | c.2368G>C p.E790Q | Missense Mutation (SNP) | VAF 59/551 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.053); catalogued as COSV71112744; called by muse, mutect2, varscan2
- AGAP5 | c.1467G>A p.W489* | Nonsense Mutation (SNP) | VAF 141/226 reads (62%) | called by muse, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 44/1495 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- RNF138 | c.75C>G p.L25= | Silent (SNP) | VAF 183/408 reads (45%) | catalogued as rs369363220; called by muse, mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 12/230 reads (5%) | called by muse, mutect2
- POF1B | c.*10C>G | 3'UTR (SNP) | VAF 323/877 reads (37%) | called by muse, mutect2, varscan2
- YIF1A | c.243+65C>A | Intron (SNP) | VAF 87/190 reads (46%) | catalogued as rs1231661487; called by muse, mutect2, varscan2
